Somatic mutation profile of tumor specimen TCGA-CQ-A4CE-01A (aliquot TCGA-CQ-A4CE-01A-11D-A25Y-08) from TCGA case TCGA-CQ-A4CE, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 76.1 years (27,793 days).
Specimen TCGA-CQ-A4CE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f3d7722-13bd-4b39-bc81-4e70a64cfb9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4CE-10A (Blood Derived Normal), aliquot TCGA-CQ-A4CE-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a61a1286-2cd3-4b8b-a000-9272d7be6739

The open-access MAF lists 72 somatic variants for this specimen: 53 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 43, Silent 19, Nonsense Mutation 6, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY7 | c.1943G>T p.C648F | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1259022797, COSV99575817; called by muse, mutect2, varscan2
- AP5M1 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 21/229 reads (9%) | catalogued as COSV55105187, COSV55106109; called by muse, mutect2
- BAIAP3 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs139609870; called by muse, mutect2, varscan2
- BPI | c.924G>T p.K308N (on ENST00000262865; = p.K304N on NM_001725.3) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV99480501; called by muse, mutect2, varscan2
- BPIFB4 | c.1440G>T p.R480S | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.089); catalogued as COSV100971471; called by muse, mutect2
- C12orf56 | c.1612C>G p.Q538E (on ENST00000543942 / NM_001170633.2; = p.Q378E on NM_001099676.3) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV100399191; called by muse, mutect2, varscan2
- C3 | c.4967T>C p.M1656T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99836339; called by muse, mutect2, varscan2
- CDK20 | c.729G>C p.K243N (on ENST00000325303 / NM_001039803.3; = p.K222N on NM_012119.4) | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV100308020; called by muse, mutect2, varscan2
- CFAP74 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1019225917; called by muse, mutect2, varscan2
- CNOT1 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs150528737; called by muse, mutect2, varscan2
- CNTN4 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as COSV100639086; called by muse, mutect2, varscan2
- COL4A1 | c.4566G>A p.W1522* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV101011031; called by muse, mutect2
- COL9A3 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756015135, COSV58983632; called by muse, mutect2
- CSNK1A1L | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as rs1405552303, COSV65790043; called by muse, mutect2
- DCAF6 | c.1681G>A p.E561K (on ENST00000312263 / NM_001349778.1; = p.E581K on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV100394082; called by muse, mutect2, varscan2
- DMP1 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 35/105 reads (33%) | catalogued as COSV99218593; called by muse, mutect2, varscan2
- DSEL | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs373569592; called by muse, mutect2, varscan2
- FAT3 | c.12371G>T p.C4124F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99963807; called by muse, mutect2, varscan2
- FBXW7 | c.1627A>G p.R543G (on ENST00000281708 / NM_001349798.2; = p.R463G on NM_018315.5) | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV55918713; called by muse, mutect2, varscan2
- GP1BA | c.934G>C p.V312L | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as COSV99850936; called by muse, mutect2
- HDAC5 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99291185; called by muse, mutect2, varscan2
- HOXB3 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs745805494, COSV100290598; called by muse, mutect2
- KCNK7 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1210951109, COSV100442089; called by muse, mutect2, varscan2
- KLHDC7A | c.1912G>A p.V638I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV101272744; called by muse, mutect2, varscan2
- MAP3K9 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs148675299; called by muse, mutect2, varscan2
- METTL27 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV99936385; called by muse, mutect2
- OR9A4 | c.30A>T p.E10D | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV101516383; called by muse, mutect2, varscan2
- PCDHA1 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65372743; called by muse, varscan2
- PCDHA13 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.285); catalogued as COSV99165419; called by muse, mutect2, varscan2
- PLXNB1 | c.4151A>G p.N1384S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.55); catalogued as COSV99602550; called by muse, mutect2, varscan2
- PNMA5 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV100721611; called by muse, mutect2
- PPL | c.3403C>T p.R1135C | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs753325015, COSV99277688; called by muse, mutect2, varscan2
- PRMT1 | c.647G>A p.W216* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV101212247; called by muse, mutect2, varscan2
- RASGRF2 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs868627910, COSV54123191; called by muse, mutect2, varscan2
- SEC23A | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs768946218, COSV100305217; called by muse, mutect2
- SPRY1 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.297); catalogued as COSV99060243; called by muse, mutect2
- SRGAP3 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV100840830; called by muse, mutect2, varscan2
- STYXL2 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 13/83 reads (16%) | catalogued as COSV99608841; called by muse, mutect2, varscan2
- TAS2R14 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773473266, COSV67862023; called by muse, mutect2
- TRANK1 | c.5858G>A p.R1953H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs763300155, COSV100082164; called by mutect2, varscan2
- USP54 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100160996; called by muse, mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 24/68 reads (35%) | catalogued as rs754083634; called by mutect2, varscan2
- ZBED2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV51913339, COSV99342587; called by muse, mutect2, varscan2
- ZNF16 | c.262T>C p.S88P | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.694); catalogued as COSV99429497; called by muse, mutect2, varscan2
- ZNF404 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1445396946, COSV100182441; called by muse, mutect2, varscan2
- ZNF813 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV101124739, COSV67176331; called by muse, mutect2
- ZSCAN18 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as rs1476960471, COSV99559056; called by muse, mutect2
- DNAH8 | c.1517dup p.L507Sfs*24 | Frame Shift Ins (INS) | VAF 35/129 reads (27%) | called by mutect2, pindel, varscan2
- FAT1 | c.11283_11287dup p.S3763Nfs*7 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- FCGBP | c.6685C>G p.P2229A | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.952); called by muse, mutect2
- PHIP | c.4109dup p.L1370Ffs*7 | Frame Shift Ins (INS) | VAF 12/104 reads (12%) | called by mutect2, pindel, varscan2
- VPS13D | c.4181G>T p.S1394I | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ABCG5 | c.234C>T p.S78= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs748628439, COSV53209401, COSV53209655; called by muse, mutect2, varscan2
- ACTRT2 | c.141C>A p.P47= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV101007564; called by muse, mutect2
- AGPAT3 | c.378G>T p.L126= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99377280; called by muse, mutect2
- AMDHD2 | c.1155C>T p.L385= (on ENST00000293971 / NM_001330449.2; = p.L415= on NM_015944.4) | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as rs749749353, COSV53550171; called by muse, mutect2, varscan2
- BPHL | c.720C>T p.H240= | Silent (SNP) | VAF 58/236 reads (25%) | catalogued as rs553521784, COSV66743002; called by muse, mutect2, varscan2
- CARF | c.147C>T p.I49= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100247571; called by muse, mutect2, varscan2
- CXXC1 | c.42G>A p.G14= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV99552237; called by muse, mutect2
- DDX3X | c.1881C>T p.H627= (on ENST00000399959; = p.H628= on NM_001356.5) | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs779341057, COSV101302337; called by muse, mutect2, varscan2
- GADD45B | c.330C>T p.G110= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99298013; called by muse, mutect2, varscan2
- GPR139 | c.987G>A p.P329= | Silent (SNP) | VAF 8/178 reads (4%) | catalogued as rs1185530060, COSV58501525, COSV58503622, COSV58503739; called by muse, mutect2
- GPR83 | c.933C>T p.Y311= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs377656693; called by muse, mutect2, varscan2
- KIR2DL3 | c.597C>T p.F199= | Silent (SNP) | VAF 74/526 reads (14%) | catalogued as rs747953308; called by muse, varscan2
- MYLK | c.696G>A p.T232= | Silent (SNP) | VAF 29/192 reads (15%) | catalogued as rs41271441, COSV60605183; called by muse, mutect2, varscan2
- SALL1 | c.3327G>A p.P1109= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs375357921; called by muse, mutect2, varscan2
- TECPR1 | c.2865C>A p.L955= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV101130336; called by muse, mutect2
- TSNAXIP1 | c.1023T>G p.A341= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99534948; called by muse, mutect2, varscan2
- TTN | c.49359C>A p.G16453= (on ENST00000591111; = p.G9029= on NM_003319.4) | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as COSV100601985; called by muse, mutect2, varscan2
- TUT4 | c.4641C>T p.H1547= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs748757276, COSV99932014; called by muse, mutect2, varscan2
- ZNF778 | c.1884C>T p.S628= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs745725204, COSV100124353, COSV100124718; called by muse, mutect2
